FM case AD17465 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/22c956e1-ac23-4971-8547-d38a6a415e34

Male, 65.8 years: Carcinoma, anaplastic, NOS (ICD-O-3 8021/3) of the thyroid gland; metastasis biopsied or resected from the thyroid gland. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
